Somatic mutation profile of tumor specimen 5504c643-4a9c-4ec4-ab07-bebdaf (aliquot 5504c643-4a9c-4ec4-ab07-bebdaf_D6) from CPTAC case 11BR075, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 79.3 years (28,956 days).
Specimen 5504c643-4a9c-4ec4-ab07-bebdaf: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f28d52e2-ae1f-48a3-a666-26e40138c4d8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen b6af20fa-c744-44ac-ab44-e3b62c (Blood Derived Normal), aliquot b6af20fa-c744-44ac-ab44-e3b62c_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9982308a-1aac-4f0f-b8f2-7f79326196fa

The open-access MAF lists 157 somatic variants for this specimen: 112 protein-altering or splice-affecting, 26 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 86, Silent 26, Frame Shift Del 10, Intron 7, Splice Site 6, Nonsense Mutation 5, 5'Flank 4, RNA 3, 5'UTR 3, In Frame Del 3, 3'UTR 2, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KDM5C | c.2080C>T p.R694* | Nonsense Mutation (SNP) | VAF 98/348 reads (28%) | catalogued as rs199422236, CM050330; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.700T>A p.Y234N | Missense Mutation (SNP) | VAF 91/237 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs864622237, CM137618, COSV52694920, COSV52730114, COSV52730255; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ACVRL1 | c.651G>T p.W217C | Missense Mutation (SNP) | VAF 129/501 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM062406; called by muse, mutect2, varscan2
- ARHGAP25 | c.1013A>G p.Q338R (on ENST00000409202 / NM_001007231.3; = p.Q330R on NM_014882.3) | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.827); catalogued as rs1325584251; called by muse, mutect2, varscan2
- CCDC178 | c.961C>A p.Q321K | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs776584133, COSV55785929; called by muse, varscan2
- CHM | c.1170G>A p.M390I | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV63304728; called by muse, mutect2
- COL20A1 | c.187A>G p.M63V | Missense Mutation (SNP) | VAF 89/203 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.127); catalogued as rs998223252; called by muse, mutect2, varscan2
- CP | c.2122G>A p.G708S | Missense Mutation (SNP) | VAF 41/154 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1056623509, CM148239, COSV52834538; called by muse, mutect2, varscan2
- CYP4V2 | c.827T>G p.M276R | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV66504996; called by muse, mutect2, varscan2
- DELE1 | c.389C>G p.S130C | Missense Mutation (SNP) | VAF 45/179 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.635); catalogued as rs747756375; called by muse, mutect2, varscan2
- FMN2 | c.2378G>A p.R793Q | Missense Mutation (SNP) | VAF 86/697 reads (12%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.006); catalogued as rs748393494, COSV60431235; called by muse, mutect2, varscan2
- GABRQ | c.1121G>T p.R374L | Missense Mutation (SNP) | VAF 94/319 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.326); catalogued as COSV64781395; called by muse, mutect2, varscan2
- GIMAP1 | c.737G>A p.R246H | Missense Mutation (SNP) | VAF 55/221 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.132); catalogued as rs1373463897, COSV100212241; called by muse, mutect2, varscan2
- GPR17 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 125/581 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs934029152; called by muse, mutect2, varscan2
- HECW2 | c.2092C>T p.Q698* | Nonsense Mutation (SNP) | VAF 41/91 reads (45%) | catalogued as COSV53665565; called by muse, mutect2, varscan2
- HSPA12A | c.976del p.H326Ifs*24 | Frame Shift Del (DEL) | VAF 30/122 reads (25%) | catalogued as COSV65023874; called by mutect2, pindel, varscan2
- IGKV2-30 | c.53C>T p.S18F | Missense Mutation (SNP) | VAF 35/181 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.076); catalogued as rs553126132; called by muse, mutect2, varscan2
- JPH1 | c.101G>A p.G34D | Missense Mutation (SNP) | VAF 119/344 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs574279181, COSV60612783; called by muse, mutect2, varscan2
- MEGF6 | c.1818C>G p.H606Q | Missense Mutation (SNP) | VAF 69/242 reads (29%) | SIFT tolerated (0.64); PolyPhen benign (0.006); catalogued as rs1413652124; called by muse, mutect2, varscan2
- MYO15B | c.3827G>A p.G1276D | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.273); catalogued as rs1411910702; called by muse, mutect2, varscan2
- MYO3A | c.4777G>T p.A1593S | Missense Mutation (SNP) | VAF 45/153 reads (29%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.001); catalogued as rs867042848; called by muse, mutect2, varscan2
- NPY | c.16C>T p.R6* | Nonsense Mutation (SNP) | VAF 166/574 reads (29%) | catalogued as COSV54215911; called by muse, varscan2
- PCLO | c.10813C>T p.R3605W | Missense Mutation (SNP) | VAF 116/662 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs766614715, COSV61623435; called by muse, mutect2, varscan2
- PNLIPRP3 | c.1316A>C p.N439T | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as COSV65048565; called by muse, mutect2, varscan2
- PTCD3 | c.1015C>G p.L339V | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54483492; called by muse, mutect2, varscan2
- RAI1 | c.2914C>G p.L972V | Missense Mutation (SNP) | VAF 12/222 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV99884759; called by muse, mutect2
- SBK3 | c.275G>A p.R92H | Missense Mutation (SNP) | VAF 52/204 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.051); catalogued as rs578100114; called by muse, mutect2, varscan2
- SHPRH | c.3958G>A p.E1320K (on ENST00000275233 / NM_001042683.3; = p.E1324K on NM_173082.3) | Missense Mutation (SNP) | VAF 12/266 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs1278915546; called by muse, mutect2
- SIPA1L2 | c.4801C>G p.H1601D | Missense Mutation (SNP) | VAF 43/311 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.062); catalogued as COSV53390023; called by muse, varscan2
- SMARCD1 | c.1052G>A p.R351H | Missense Mutation (SNP) | VAF 64/244 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.487); catalogued as rs746406610; called by muse, mutect2, varscan2
- STAG1 | c.2639T>G p.I880S | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as rs1422066973; called by muse, mutect2, varscan2
- TBX6 | c.656G>T p.R219L | Missense Mutation (SNP) | VAF 66/208 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs560931949, COSV54221403; called by muse, varscan2
- TTN | c.42755G>C p.G14252A (on ENST00000591111; = p.G6828A on NM_003319.4) | Missense Mutation (SNP) | VAF 9/88 reads (10%) | PolyPhen probably damaging (0.999); catalogued as rs1224613366; called by muse, mutect2, varscan2
- UNC5D | c.1775C>G p.S592* | Nonsense Mutation (SNP) | VAF 20/63 reads (32%) | catalogued as COSV54837479; called by muse, mutect2, varscan2
- ACTL9 | c.667C>G p.L223V | Missense Mutation (SNP) | VAF 74/263 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.422); called by muse, mutect2, varscan2
- AFDN | c.386del p.K129Rfs*94 | Frame Shift Del (DEL) | VAF 37/89 reads (42%) | called by mutect2, pindel, varscan2
- AL139011.2 | c.482_485del p.Y161Lfs*18 | Frame Shift Del (DEL) | VAF 39/242 reads (16%) | called by mutect2, pindel, varscan2
- ARHGAP24 | c.91G>T p.G31C | Missense Mutation (SNP) | VAF 47/177 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ASAP2 | c.1486G>C p.G496R | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT tolerated (0.76); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- ASZ1 | c.670A>G p.R224G | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- BMP3 | c.610C>T p.Q204* | Nonsense Mutation (SNP) | VAF 43/273 reads (16%) | called by muse, mutect2, varscan2
- C10orf90 | c.1738_1752del p.K580_I584del | In Frame Del (DEL) | VAF 35/143 reads (24%) | called by mutect2, pindel*, varscan2*
- C3orf70 | c.11_35del p.A4Vfs*7 | Frame Shift Del (DEL) | VAF 24/149 reads (16%) | called by mutect2, pindel, varscan2
- CCDC80 | c.1835T>A p.V612E | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- CCDC85B | c.48G>A p.M16I | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CCDC92 | c.220A>G p.T74A | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CFAP57 | c.1468A>T p.N490Y | Missense Mutation (SNP) | VAF 82/343 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- CFAP69 | c.635T>C p.V212A | Missense Mutation (SNP) | VAF 45/111 reads (41%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHI3L2 | c.960G>C p.Q320H | Missense Mutation (SNP) | VAF 84/362 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.673); called by muse, varscan2
- CHSY3 | c.1326G>C p.E442D | Missense Mutation (SNP) | VAF 90/316 reads (28%) | SIFT tolerated (0.53); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- COIL | c.1684C>A p.L562M | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- COL9A1 | c.2240C>A p.P747H | Missense Mutation (SNP) | VAF 304/790 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by mutect2, varscan2
- ERICH1 | c.1306A>G p.I436V | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- EXOSC3 | c.827G>C p.*276Sext*10 | Nonstop Mutation (SNP) | VAF 23/68 reads (34%) | called by muse, mutect2, varscan2
- FAM170B | c.295_314del p.D99Cfs*35 | Frame Shift Del (DEL) | VAF 84/330 reads (25%) | called by mutect2, varscan2
- FBXO44 | c.92G>C p.R31P | Missense Mutation (SNP) | VAF 111/484 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FLG | c.6337G>C p.G2113R | Missense Mutation (SNP) | VAF 149/607 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- FYB2 | c.919+2_919+29del p.X307_splice | Splice Site (DEL) | VAF 14/139 reads (10%) | called by mutect2, pindel, varscan2
- GBF1 | c.5303A>C p.D1768A (on ENST00000369983 / NM_001377137.1; = p.D1767A on NM_004193.3) | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated, low confidence (0.26); PolyPhen possibly damaging (0.661); called by muse, mutect2, varscan2
- GCC1 | c.2319del p.K774Rfs*63 | Frame Shift Del (DEL) | VAF 18/83 reads (22%) | called by mutect2, pindel, varscan2
- GPN1 | c.786del p.E263Kfs*14 | Frame Shift Del (DEL) | VAF 12/61 reads (20%) | called by mutect2, pindel, varscan2
- GPRC5C | c.597G>C p.W199C (on ENST00000652232; = p.W154C on NM_018653.4) | Missense Mutation (SNP) | VAF 92/380 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- GSTA1 | c.177G>C p.E59D | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.573); called by muse, mutect2
- HACE1 | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 52/290 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- HECTD1 | c.293C>G p.A98G | Missense Mutation (SNP) | VAF 52/178 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- HMCN1 | c.15320-1del p.X5107_splice | Splice Site (DEL) | VAF 32/201 reads (16%) | called by mutect2, pindel, varscan2
- IGF2R | c.563C>G p.P188R | Missense Mutation (SNP) | VAF 28/199 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITGAM | c.2810C>A p.T937N (on ENST00000648685 / NM_001145808.2; = p.T936N on NM_000632.4) | Missense Mutation (SNP) | VAF 22/175 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- KCNIP1 | c.232G>A p.G78S (on ENST00000411494 / NM_001034837.3; = p.G67S on NM_014592.4) | Missense Mutation (SNP) | VAF 44/227 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIF15 | c.63-2A>C p.X21_splice | Splice Site (SNP) | VAF 16/49 reads (33%) | called by muse, mutect2, varscan2
- KMT2C | c.10420_10468del p.Q3474Kfs*21 | Frame Shift Del (DEL) | VAF 106/432 reads (25%) | called by mutect2, pindel
- KPNA7 | c.748C>A p.L250M | Missense Mutation (SNP) | VAF 67/417 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- LEPR | c.3365A>G p.H1122R | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- LPCAT4 | c.1126T>A p.F376I | Missense Mutation (SNP) | VAF 49/181 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- LRRC3B | c.223C>G p.Q75E | Missense Mutation (SNP) | VAF 105/396 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- LSAMP | c.394C>A p.P132T | Missense Mutation (SNP) | VAF 39/177 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- MAGEA10 | c.415_426del p.T139_V142del | In Frame Del (DEL) | VAF 46/189 reads (24%) | called by mutect2, varscan2
- MATR3 | c.287C>G p.P96R | Missense Mutation (SNP) | VAF 47/150 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- MCTP2 | c.1664_1685+7del p.X555_splice | Splice Site (DEL) | VAF 52/120 reads (43%) | called by mutect2, pindel, varscan2
- MFAP3L | c.457T>A p.Y153N | Missense Mutation (SNP) | VAF 93/450 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NACA2 | c.66G>C p.E22D | Missense Mutation (SNP) | VAF 106/433 reads (24%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.535); called by muse, mutect2, varscan2
- NOTCH3 | c.4550T>G p.V1517G | Missense Mutation (SNP) | VAF 79/250 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- NPY | c.97C>A p.P33T | Missense Mutation (SNP) | VAF 178/680 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- NR5A2 | c.904C>A p.P302T (on ENST00000367362 / NM_205860.3; = p.P256T on NM_003822.5) | Missense Mutation (SNP) | VAF 81/486 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- NUP54 | c.924C>G p.I308M | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); called by muse, mutect2
- NUTM2F | c.1917G>A p.M639I | Missense Mutation (SNP) | VAF 99/402 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- OR7D4 | c.875T>A p.L292Q | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- P2RY1 | c.291C>A p.D97E | Missense Mutation (SNP) | VAF 155/665 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PAPPA | c.1933G>A p.D645N | Missense Mutation (SNP) | VAF 37/171 reads (22%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- PEX14 | c.476T>G p.V159G | Missense Mutation (SNP) | VAF 106/370 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- PNMA2 | c.32G>A p.R11K | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- PPIP5K2 | c.3609C>G p.S1203R (on ENST00000358359 / NM_001276277.3; = p.S1182R on NM_015216.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- PREX2 | c.2318C>A p.S773Y | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- PRSS36 | c.1522-1G>C p.X508_splice | Splice Site (SNP) | VAF 67/289 reads (23%) | called by muse, mutect2, varscan2
- RHOBTB1 | c.1138G>A p.G380S | Missense Mutation (SNP) | VAF 103/278 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RUNX1 | c.449_468del p.I150Tfs*29 (on ENST00000344691 / NM_001001890.3; = p.I177Tfs*29 on NM_001754.5) | Frame Shift Del (DEL) | VAF 169/508 reads (33%) | called by mutect2, varscan2
- SLC9C2 | c.1989A>T p.K663N | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- SMARCA1 | c.2825_2859del p.R942Ifs*11 | Frame Shift Del (DEL) | VAF 17/79 reads (22%) | called by mutect2, pindel, varscan2
- SMARCA2 | c.1991C>T p.P664L | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SPEN | c.9278T>G p.L3093R | Missense Mutation (SNP) | VAF 81/261 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ST6GALNAC4 | c.12+5G>T | Splice Region (SNP) | VAF 30/158 reads (19%) | called by muse, varscan2
- TBC1D15 | c.344-1G>T p.X115_splice | Splice Site (SNP) | VAF 10/189 reads (5%) | called by muse, mutect2
- TCP1 | c.487A>T p.I163L | Missense Mutation (SNP) | VAF 30/169 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- TNR | c.2797C>T p.L933F | Missense Mutation (SNP) | VAF 61/336 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- TNRC6C | c.619A>T p.N207Y | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- TRIM32 | c.344G>T p.C115F | Missense Mutation (SNP) | VAF 134/600 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TRPM1 | c.4640C>T p.S1547F | Missense Mutation (SNP) | VAF 99/413 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- UNC5D | c.2289A>T p.R763S | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- VWDE | c.293C>T p.S98L | Missense Mutation (SNP) | VAF 73/327 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- WDR93 | c.316C>G p.P106A | Missense Mutation (SNP) | VAF 31/148 reads (21%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.509); called by muse, mutect2, varscan2
- ZNF324 | c.131C>A p.T44N | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- ZNF787 | c.470_493del p.R157_S164del | In Frame Del (DEL) | VAF 13/52 reads (25%) | called by mutect2, pindel, varscan2
- ALDH18A1 | c.1521G>A p.K507= | Silent (SNP) | VAF 162/605 reads (27%) | catalogued as rs1453590181; called by muse, mutect2, varscan2
- ANKRD11 | c.717C>T p.H239= | Silent (SNP) | VAF 195/690 reads (28%) | catalogued as rs753274554; called by muse, mutect2, varscan2
- AOPEP | c.2136C>T p.V712= (on ENST00000375315 / NM_001193329.1; = p.V613= on NM_032823.5) | Silent (SNP) | VAF 43/157 reads (27%) | called by muse, mutect2, varscan2
- APOB | c.6231G>A p.L2077= | Silent (SNP) | VAF 21/146 reads (14%) | catalogued as rs769417863; called by muse, mutect2, varscan2
- ARNT2 | c.1860T>C p.A620= | Silent (SNP) | VAF 39/155 reads (25%) | called by muse, mutect2, varscan2
- ATP2C1 | c.2106C>T p.F702= | Silent (SNP) | VAF 42/145 reads (29%) | catalogued as COSV100146663, COSV60754905; called by muse, mutect2, varscan2
- C10orf71 | c.2400G>A p.L800= | Silent (SNP) | VAF 33/121 reads (27%) | called by muse, mutect2, varscan2
- DIP2B | c.2764C>T p.L922= | Silent (SNP) | VAF 36/185 reads (19%) | catalogued as COSV99999340; called by muse, mutect2, varscan2
- GIMAP8 | c.987G>A p.L329= | Silent (SNP) | VAF 145/242 reads (60%) | catalogued as rs1440323906, COSV56229657, COSV56234321; called by muse, mutect2, varscan2
- KIF12 | c.366C>G p.P122= | Silent (SNP) | VAF 22/66 reads (33%) | called by muse, mutect2, varscan2
- MAGEB6 | c.777C>G p.G259= | Silent (SNP) | VAF 17/88 reads (19%) | catalogued as COSV100983642; called by muse, mutect2, varscan2
- MYBPC3 | c.2535C>T p.R845= | Silent (SNP) | VAF 32/113 reads (28%) | catalogued as rs1288578869; called by muse, mutect2, varscan2
- MYLK2 | c.1368T>C p.Y456= | Silent (SNP) | VAF 350/864 reads (41%) | called by muse, mutect2, varscan2
- NAGPA | c.207G>T p.A69= | Silent (SNP) | VAF 4/14 reads (29%) | called by muse, varscan2
- NEK2 | c.231G>A p.R77= | Silent (SNP) | VAF 17/186 reads (9%) | called by muse, mutect2
- NLRX1 | c.2889C>T p.V963= | Silent (SNP) | VAF 9/174 reads (5%) | catalogued as COSV52710493; called by muse, mutect2
- PFKL | c.2175C>G p.L725= | Silent (SNP) | VAF 54/201 reads (27%) | called by muse, mutect2, varscan2
- PRSS36 | c.474C>G p.V158= | Silent (SNP) | VAF 13/286 reads (5%) | called by muse, mutect2
- RTTN | c.435T>C p.F145= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as COSV55349521; called by muse, mutect2, varscan2
- SMS | c.627C>T p.V209= | Silent (SNP) | VAF 101/419 reads (24%) | called by muse, mutect2, varscan2
- TPRG1 | c.396T>C p.C132= | Silent (SNP) | VAF 48/266 reads (18%) | called by mutect2, varscan2
- TSSK6 | c.396G>C p.V132= | Silent (SNP) | VAF 60/282 reads (21%) | called by muse, mutect2, varscan2
- TUBB | c.249G>A p.Q83= | Silent (SNP) | VAF 20/58 reads (34%) | called by muse, mutect2, varscan2
- UHMK1 | c.804G>A p.V268= | Silent (SNP) | VAF 10/111 reads (9%) | catalogued as rs1298623318; called by muse, mutect2
- WDR17 | c.3834G>A p.T1278= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as rs145267415; called by muse, mutect2, varscan2
- ZPLD1 | c.705C>T p.C235= (on ENST00000466937 / NM_001329788.1; = p.C251= on NM_175056.2) | Silent (SNP) | VAF 10/54 reads (19%) | called by muse, mutect2, varscan2
- ADGRV1 | c.*50T>C | 3'UTR (SNP) | VAF 24/88 reads (27%) | called by mutect2, varscan2
- ARFRP1 | c.417+474C>T | Intron (SNP) | VAF 43/171 reads (25%) | called by muse, mutect2, varscan2
- EARS2 | chr16:23557498 C>T | 5'Flank (SNP) | VAF 12/30 reads (40%) | called by muse, mutect2, varscan2
- EPOR | c.-70C>T | 5'UTR (SNP) | VAF 48/167 reads (29%) | catalogued as rs1041286010; called by muse, varscan2
- HPD | c.241+43G>T | Intron (SNP) | VAF 91/292 reads (31%) | called by muse, mutect2, varscan2
- IGFN1 | c.1242-1560A>G | Intron (SNP) | VAF 21/90 reads (23%) | called by muse, mutect2, varscan2
- KCNIP3 | c.181+168G>C | Intron (SNP) | VAF 48/160 reads (30%) | called by muse, mutect2, varscan2
- LMF1 | chr16:975959 C>T | 5'Flank (SNP) | VAF 69/306 reads (23%) | called by muse, mutect2, varscan2
- MGAT4A | c.*4104C>T | 3'UTR (SNP) | VAF 33/130 reads (25%) | called by muse, mutect2, varscan2
- MGAT4FP | n.754_773del | RNA (DEL) | VAF 22/251 reads (9%) | called by mutect2, pindel
- MID2 | c.-29G>A | 5'UTR (SNP) | VAF 15/68 reads (22%) | called by muse, mutect2, varscan2
- MOG | c.730+150G>C | Intron (SNP) | VAF 46/147 reads (31%) | called by muse, varscan2
- MUSK | c.628+8617A>T | Intron (SNP) | VAF 31/91 reads (34%) | called by muse, mutect2, varscan2
- PMEL | chr12:55970963 C>T | 5'Flank (SNP) | VAF 97/300 reads (32%) | called by muse, mutect2, varscan2
- REXO1L1P | chr8:85663412 C>T | 5'Flank (SNP) | VAF 54/1130 reads (5%) | called by muse, mutect2
- SECISBP2 | c.-17C>G | 5'UTR (SNP) | VAF 22/61 reads (36%) | called by muse, mutect2, varscan2
- SUMO2P21 | n.10G>A | RNA (SNP) | VAF 50/150 reads (33%) | called by muse, mutect2, varscan2
- TMEM132B | c.1422+68C>T | Intron (SNP) | VAF 40/188 reads (21%) | called by muse, mutect2, varscan2
- ZNF833P | n.1009C>T | RNA (SNP) | VAF 39/140 reads (28%) | called by muse, mutect2, varscan2
